Somatic mutation profile of tumor specimen C3N-01011-02 (aliquot CPT0065640009_1) from CPTAC case C3N-01011, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 77.5 years (28,289 days).
Specimen C3N-01011-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 37bff077-f8d8-47fe-b0e3-f511b1ac6480.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01011-31 (Blood Derived Normal), aliquot CPT0070720002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3bae62e4-e6ba-4fa0-b7c8-f14bd588d374

The open-access MAF lists 19 somatic variants for this specimen: 13 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 5, Nonsense Mutation 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 42/868 reads (5%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2
- GON4L | c.4669C>A p.P1557T | Missense Mutation (SNP) | VAF 31/532 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.346); catalogued as COSV55196384; called by muse, mutect2
- IL17RA | c.1918G>A p.G640R | Missense Mutation (SNP) | VAF 15/251 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs1221696207; ClinVar: uncertain significance; called by muse, mutect2
- NKX2-5 | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 39/575 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1366528649; called by muse, mutect2
- SERPINE3 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 51/732 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as rs371975326; called by muse, mutect2
- SHANK3 | c.3610G>A p.V1204I | Missense Mutation (SNP) | VAF 44/955 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.131); catalogued as rs1339032405, COSV53189742; called by muse, mutect2
- WNK4 | c.1886G>A p.R629H | Missense Mutation (SNP) | VAF 64/1075 reads (6%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.513); catalogued as rs781142521; called by muse, mutect2
- MMP21 | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2
- NCOA6 | c.4826C>G p.S1609* | Nonsense Mutation (SNP) | VAF 18/335 reads (5%) | called by muse, mutect2
- OR2L2 | c.177T>A p.Y59* | Nonsense Mutation (SNP) | VAF 24/351 reads (7%) | called by muse, mutect2
- RYR1 | c.1309A>G p.I437V | Missense Mutation (SNP) | VAF 27/552 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.119); called by muse, mutect2
- SNX15 | c.86A>G p.K29R | Missense Mutation (SNP) | VAF 24/376 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); called by muse, mutect2
- SYMPK | c.3752G>T p.G1251V | Missense Mutation (SNP) | VAF 10/223 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2
- ATP1A2 | c.201G>A p.Q67= | Silent (SNP) | VAF 45/722 reads (6%) | called by muse, mutect2
- LPAR4 | c.714T>C p.S238= | Silent (SNP) | VAF 21/425 reads (5%) | called by muse, mutect2
- PLXND1 | c.1179C>T p.F393= | Silent (SNP) | VAF 11/348 reads (3%) | called by muse, mutect2
- RAB3GAP2 | c.2973C>T p.A991= | Silent (SNP) | VAF 38/746 reads (5%) | catalogued as COSV100741147; called by muse, mutect2
- TF | c.1782G>A p.A594= | Silent (SNP) | VAF 25/442 reads (6%) | catalogued as rs778400078, COSV53917621; called by muse, mutect2
- NCF4 | c.758+63T>C | Intron (SNP) | VAF 32/736 reads (4%) | called by muse, mutect2
